Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A2RA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A2RA-01A (Primary Tumor).

[page 1 of 6]
PAGE 1

ANATOMIC PATHOLOGY REPORT FAX

PATIENT:
D.O.B.:
SPECIMEN #:
Physician:
Oth Phy(s):

Received
Accessioned:

CLINICAL HISTORY

ICD-0-3

CLINICAL HISTORY: CERVICAL VERSUS ENDOMETRIAL CA
PROCEDURE/FINDINGS: RADICAL HYSTERECTOMY
SPECIMEN(S):

- A. VAGINAL MARGINS FOR FROZEN
- B. UTERUS, BSO AND CERVIX
- C. RIGHT PELVIC LYMPH NODE DISSECTION
- D. LEFT AORTIC
- E. LEFT PELVIC LYMPH NODE DISSECTION
- F. RIGHT PERIAORTIC

*carcinoma, squamous cell,
nonkeratinizing, NOS 8072/3
site: cervix, NOS C53.9*

*hw
9/8/11*

FINAL DIAGNOSIS

- A. VAGINAL MARGIN, EXCISION:
NEGATIVE FOR INVASIVE CARCINOMA.
SURFACE EPITHELIUM SHOWS CHANGES CONSISTENT WITH HIGH GRADE SQUAMOUS INTRAEPITHELIAL LESION (CIN II AT LEAST) AND MARKED THERMAL ARTIFACT.
- B. UTERUS, CERVIX, AND BILATERAL TUBES AND OVARIES, RADICAL HYSTERECTOMY:
INVASIVE SQUAMOUS CELL CARCINOMA, NON-KERATINIZING.
Tumor location: INVOLVES ENTIRE CERVIX WITH EXTENSION INTO THE UTERINE CORPUS.
Tumor size: 5.5 X 5.0 X 2.0 CM.
Histologic grade: HIGH GRADE.
Maximal thickness of cervical stromal invasion: 1.0 CM.
Thickness of stroma in area of maximal tumor invasion: 1.2 CM.
Lymphatic/vascular invasion: ABSENT.
Margins: NEGATIVE FOR INVASIVE SQUAMOUS CELL CARCINOMA.
0.2 CM AWAY FROM VAGINAL CUFF MARGIN.
VAGINAL MARGIN SHOWS HSIL (SEE PART A)

[page 2 of 6]
PAGE 2

ANATOMIC PATHOLOGY REPORT FAX

PATIENT:
D.O.B.:
SPECIMEN #:
Physician:
Oth Phy(s):

Collected:
Received:
Accessioned:

FINAL DIAGNOSIS

(Continued)

Extension to uterine corpus: PRESENT, EXTENSIVE INVOLVEMENT. INVADES MYOMETRIUM
AT A DEPTH OF 1.5 CM WITH A MAXIMAL MYOMETRIAL THICKNESS OF 1.6 CM
IN THIS AREA.

Parametrial involvement: ABSENT.

Lymph nodes: NEGATIVE, SEE PARTS C-F.

AJCC pTNM CLASSIFICATION:

T1a2 NO MX

FIGO STAGE: 1A2

- C. LYMPH NODES, RIGHT PELVIC, EXCISION:
TEN BENIGN LYMPH NODES, NEGATIVE FOR TUMOR (0/10).
- D. LYMPH NODES, LEFT AORTIC, EXCISION:
SEVEN BENIGN LYMPH NODES, NEGATIVE FOR TUMOR (0/7).
- E. LYMPH NODES, LEFT PELVIC, EXCISION:
EIGHT BENIGN LYMPH NODES, NEGATIVE FOR TUMOR (0/8).
- F. LYMPH NODES, RIGHT PERIAORTIC, EXCISION:
SEVEN BENIGN LYMPH NODES, NEGATIVE FOR TUMOR (0/7).

Dictated by:

[page 3 of 6]
ANATOMIC PATHOLOGY REPORT FAX

PATIENT:
D.O.B.:
SPECIMEN #:
Physician:
Oth Phy(s):

Collected:
Received:
Accessioned:

GROSS DESCRIPTION

A. The specimen is received fresh labeled "[redacted] vaginal margin" and consists of an irregular segment of tan-pink mucosa-covered soft tissue, 1.0 x 0.5 excised to a depth of 1.0 cm. The resected margin is inked black and the specimen is bisected and entirely submitted for frozen section as FSA.

B. The specimen is received fresh labeled "[redacted] uterus, bilateral salpingo-oophorectomy and cervix" and consists of a uterus and cervix with right tube and ovary and possible left tube that weighs 104 gm and measures 8.0 cm in length x 4.5 cm between the cornua and 3.5 cm in AP thickness. The uterus was previously opened by the surgeon. In the fresh state, a portion of the tumor was submitted for and studies. The parametrial tissue is inked black. The serosa is tan-pink, smooth and unremarkable. The ectocervix is tan-pink and demonstrates focal red-purple areas. The endocervical canal is stenotic and the uterine cavity is patent. The cervix and lower uterine segment demonstrates multiple gray-white rubbery to firm nodular areas that measure up to 1.0 cm in greatest dimension. The endometrium demonstrates multiple gray-white rubbery to firm nodular areas. These areas occupy approximately 90% of the endometrium and surrounding myometrial tissue. Sections through these areas demonstrate a tan-gray ill-defined rubbery to firm mass that measures 3.5 x 3.0 x 2.0 cm. The greatest depth of invasion is 1.5 cm. The myometrium in this area measures 1.6 cm. The mass grossly appears to involve over 90% of the myometrium. The right ovary measures 2.5 x 2.0 x 0.8 cm. The outer surface is yellow-tan and convoluted. Sections demonstrate unremarkable cut surfaces. The attached fimbriated fallopian tube measures 5.0 x 0.4 cm. Sections demonstrate a pinpoint patent lumen. The left probable fallopian tube measures 5.5 x 0.4 cm. The left ovary is not present. The case is reviewed with and sectioned per his direction. Representative sections of the specimen are submitted as follows: B1 right parametrium; B2 left parametrium; B3 serosa; B4-B7 representative full thickness section of cervix each quadrant, sequentially submitted from 1 to 12 o'clock; B8-B11 full thickness endomyometrium, anterior submitted sequentially from fundus to os; B12-B15 full thickness endomyometrium, posterior submitted sequentially from fundus to os; B16 right tube and ovary; B17 probable left tube.

[page 4 of 6]
PAGE 4

ANATOMIC PATHOLOGY REPORT FAX

PATIENT:
D.O.B.:
SPECIMEN #:
Physician:
Oth Phy(s):

Collected:
Received:
Accessioned:

GROSS DESCRIPTION

(Continued)

C. The specimen is received fresh labeled "_____, right pelvic lymph node dissection" and consists of multiple segments of golden yellow lobulated adipose tissue, 6.5 x 4.0 x 2.0 cm. Identified within the fat are ten probable lymph nodes that range from 0.2 to 5.0 cm in maximum dimension. The lymph nodes are entirely submitted as: C1 three lymph nodes; C2 one lymph node; C3-C6 one lymph node each cassette, bisected; C7-C9 one lymph node, serially sectioned; C10-C13 largest lymph node, serially sectioned.

D. The specimen is received fresh labeled "_____, left aortic lymph nodes" and consists of multiple irregular segments of dull yellow lobulated adipose tissue, 4.0 x 2.5 x 1.0 cm in loose aggregate. Identified within the fat are seven probable lymph nodes that range from 0.3 to 2.0 cm in maximum dimension. The lymph nodes are entirely submitted as: D1-D2 three lymph nodes each cassette; D3 one lymph node, bisected.

E. The specimen is received fresh labeled "_____, left pelvic" and consists of multiple segments of golden yellow lobulated adipose tissue, 6.0 x 4.0 x 2.5 cm. Identified within the fat are eight probable lymph nodes that range from 0.5 to 3.0 cm in maximum dimension. The lymph nodes are entirely submitted as: E1 three lymph nodes; E2 two lymph nodes; E4-E6 one lymph node, serially sectioned; E7-E10 largest lymph node, serially sectioned.

F. The specimen is received fresh labeled "_____, right periaortic lymph nodes" and consists of multiple fragments of golden yellow lobulated adipose tissue, 4.0 x 3.0 x 1.5 cm in loose aggregate. Identified within the fat are seven probable lymph nodes that range from 0.5 to 4.0 cm in maximum dimension. The lymph nodes are entirely submitted as: F1 three lymph nodes; F2 one lymph node; F3-F4 one lymph node each cassette, bisected; F5-F6 one lymph node, quadrisected.

[page 5 of 6]
PAGE 5

ANATOMIC PATHOLOGY REPORT FAX

PATIENT:
D.O.B.:
SPECIMEN #:
Physician:
Oth Phy(s):

Collected:
Received:
Accessioned:

MICROSCOPIC/COMMENT

A. Sections show vaginal mucosa. There is a focus of epithelium with marked thermal artifact that shows occasional mid level mitoses and nuclear atypia consistent with HGSIL (CIN grade 2 at least). No invasive squamous cell carcinoma is identified. Bentz has reviewed this part and agrees with the diagnosis.

B. Sections show cervix and uterus with a 5.5 cm in greatest dimension invasive squamous cell carcinoma with high grade features. No keratinization is seen in the tumor. The tumor arises in the cervix and extensively involves the entire cervix, endocervix, lower uterine segment and the majority of the uterine corpus. The tumor has a maximal cervical stromal invasion of 1.0 cm and this area of cervix shows a maximal thickness of 1.2 cm. No lymphovascular invasion is seen. The margins are negative for invasive squamous cell carcinoma. The invasive tumor is 0.2 cm away from the vaginal cuff margin. Most of the squamous epithelium at the vaginal cuff margin is sloughed off and marked thermal artifact is present. Please refer to part A (vaginal margin shows HGSIL). No parametrial involvement is seen. The right ovary and tube show no involvement. No definite left fallopian tube or ovary are identified grossly or microscopically. Bentz has also reviewed this case and agrees with the diagnosis invasive SCC.

C. Sections show ten benign lymph nodes. Negative for metastatic squamous cell carcinoma.

D. Sections show seven benign lymph nodes. Negative for metastatic squamous cell carcinoma.

E. Sections show eight benign lymph nodes. Negative for metastatic carcinoma.

F. Sections show seven benign lymph nodes. Negative for metastatic carcinoma.

7

[page 6 of 6]
PAGE 6

ANATOMIC PATHOLOGY REPORT FAX

PATIENT: /	Collected:
D.O.B.:	Received
SPECIMEN #:	Accessioned:
Physician: 2	
Oth Phy(s):	

INTERPRETATION PERFORMED AT:
1

Final:

by

Pt Name: A
Attend Dr:
Accts: [REDACTED]
Unit: [REDACTED]
SSN: [REDACTED]

Source: NCI Genomic Data Commons file 950765a1-dd80-4f76-8690-7c10e08ba7c5 (TCGA-EK-A2RA.4BF58062-E21B-4C5E-91D3-8AB242D8D62E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).